Somatic mutation profile of tumor specimen ALCH-AE2C-TTP1-A (aliquot ALCH-AE2C-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE2C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.4 years (21,317 days).
Specimen ALCH-AE2C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36b720aa-f2d6-40cc-9da5-fdbc40266e89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2C-NB1-A (Blood Derived Normal), aliquot ALCH-AE2C-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ab05843-d431-4613-9337-2284c7ae73f5

The open-access MAF lists 395 somatic variants for this specimen: 256 protein-altering or splice-affecting, 82 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 82, Intron 30, Nonsense Mutation 19, RNA 9, 3'Flank 5, 5'UTR 5, Splice Site 4, 5'Flank 4, Splice Region 4, 3'UTR 4, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD40LG | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205606, CM147296; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EPHB1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 42/408 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1338928289, COSV67655119; called by muse, mutect2, varscan2
- KMT2D | c.11149C>T p.Q3717* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as rs398123704, CM105473, COSV56419367; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.72G>C p.W24C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960212, COSV67961561; called by muse, mutect2, varscan2
- NFIX | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 15/227 reads (7%) | catalogued as rs1555705276; ClinVar: pathogenic; called by muse, mutect2
- AGTPBP1 | c.2863A>G p.I955V (on ENST00000357081 / NM_001330701.2; = p.I915V on NM_015239.2) | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs748522429; called by muse, mutect2, varscan2
- ANKRD29 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866249512, COSV52424818; called by muse, mutect2, varscan2
- ANKRD44 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 82/621 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV56549849, COSV56553196; called by muse, mutect2, varscan2
- ASXL2 | c.811G>T p.V271F | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs954846035, COSV55456503; called by muse, mutect2, varscan2
- ATAD2 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs556643415; called by muse, mutect2
- C10orf90 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV52960893, COSV52964183; called by muse, mutect2, varscan2
- CD1E | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100937090; called by muse, mutect2
- CDH11 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs879244499; called by muse, mutect2, varscan2
- CDK13 | c.3091A>G p.M1031V | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs1485604617; called by muse, mutect2, varscan2
- CPED1 | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 16/232 reads (7%) | catalogued as rs1282159328; called by muse, mutect2
- CSMD3 | c.5293C>T p.R1765C (on ENST00000297405 / NM_001363185.1; = p.R1661C on NM_052900.3) | Missense Mutation (SNP) | VAF 66/742 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768648527, COSV52308765; called by muse, mutect2
- CSRNP1 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs764039494; called by muse, mutect2, varscan2
- DNAJB11 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs753543507; called by muse, mutect2, varscan2
- DSC3 | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 31/471 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV64573086; called by muse, mutect2
- DYM | c.1523G>C p.R508T | Missense Mutation (SNP) | VAF 71/638 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53995623; called by muse, mutect2, varscan2
- EFCC1 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1228838504; called by muse, mutect2, varscan2
- ELANE | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM097557; called by muse, mutect2, varscan2
- FANCD2 | c.2606-1G>C p.X869_splice | Splice Site (SNP) | VAF 31/209 reads (15%) | catalogued as COSV55033028; called by muse, mutect2, varscan2
- FHOD3 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1238368366, COSV57164579; called by muse, mutect2
- FLG | c.4421G>T p.R1474L | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as rs200551704, COSV64238911; called by muse, mutect2, varscan2
- FOXI3 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs369600524; called by muse, mutect2, varscan2
- FSCB | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.12); catalogued as COSV61217224; called by muse, varscan2
- GABRG3 | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 68/455 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV61536652; called by muse, mutect2, varscan2
- GPI | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.992); catalogued as rs575607644, COSV62894873; called by muse, mutect2, varscan2
- H1-8 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs774991480; called by muse, mutect2
- HEATR5A | c.5293G>C p.E1765Q | Missense Mutation (SNP) | VAF 62/437 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1466687843; called by muse, mutect2, varscan2
- HIF1A | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as rs749686395; called by muse, mutect2, varscan2
- HLA-C | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs75512631; called by muse, mutect2, varscan2
- HOOK1 | c.1083A>T p.L361F | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774836709, COSV64619270; called by muse, mutect2, varscan2
- IBA57 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773534915, COSV64510771; called by muse, mutect2, varscan2
- KIF21A | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 43/402 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62774220; called by muse, mutect2, varscan2
- KNL1 | c.5857C>T p.R1953C (on ENST00000346991 / NM_170589.5; = p.R1927C on NM_144508.5) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs763710491, COSV100705995, COSV61154798; called by muse, varscan2
- LAMB4 | c.4806G>C p.K1602N | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV52716574; called by muse, mutect2
- LIMA1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100372191, COSV57965646; called by muse, mutect2, varscan2
- LIN37 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 41/396 reads (10%) | catalogued as COSV99137374; called by muse, mutect2
- LMTK2 | c.3352G>C p.E1118Q | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV51991672; called by muse, mutect2, varscan2
- LMX1B | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM012778; called by muse, mutect2, varscan2
- LRP1B | c.6294G>C p.W2098C | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67239128; called by muse, mutect2
- MACF1 | c.9834G>C p.E3278D | Missense Mutation (SNP) | VAF 31/248 reads (13%) | catalogued as COSV57109479; called by muse, mutect2, varscan2
- MIDN | c.767C>A p.A256D | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56295141; called by muse, mutect2, varscan2
- MOSPD3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.825); catalogued as rs745935901; called by muse, mutect2
- MYCBP2 | c.10966C>T p.H3656Y (on ENST00000357337; = p.H3694Y on NM_015057.5) | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62015700; called by muse, mutect2, varscan2
- NDUFV2 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV59187598; called by muse, mutect2
- NEIL1 | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 19/352 reads (5%) | catalogued as COSV100748504; called by muse, mutect2
- NIPSNAP1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV99331198; called by muse, mutect2
- OR10Q1 | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs112618165, COSV57469712; called by muse, mutect2, varscan2
- OR1J1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99403277; called by muse, mutect2, varscan2
- OR6K2 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.16); catalogued as COSV62743436; called by muse, mutect2, varscan2
- PCBP2 | c.956C>T p.A319V (on ENST00000439930 / NM_001128911.2; = p.A320V on NM_005016.6) | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV63728829; called by muse, mutect2
- PLA2G7 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV51258294; called by muse, mutect2
- PLAAT5 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 33/312 reads (11%) | catalogued as COSV57137826; called by muse, mutect2
- PLS1 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV100538282; called by muse, mutect2, varscan2
- PLXND1 | c.4431G>C p.K1477N | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100140635, COSV60719137; called by muse, mutect2
- POM121C | c.3429C>G p.F1143L (on ENST00000607367; = p.F901L on NM_001099415.3) | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV57544844; called by muse, varscan2
- PRMT9 | c.493A>C p.I165L | Missense Mutation (SNP) | VAF 50/447 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100482000, COSV59361524; called by muse, mutect2, varscan2
- PTCH2 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140845138; called by mutect2, varscan2
- RAD54L2 | c.3108del p.H1037Mfs*8 | Frame Shift Del (DEL) | VAF 20/167 reads (12%) | catalogued as COSV56580243; called by mutect2, pindel, varscan2
- RGPD4 | c.3652G>C p.E1218Q | Missense Mutation (SNP) | VAF 52/884 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.205); catalogued as rs549518939, COSV100736254; called by muse, mutect2
- RPSA | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 35/668 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as rs1033871561; called by muse, mutect2
- SALL3 | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs372135988; called by muse, mutect2, varscan2
- SEC14L6 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 33/414 reads (8%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.446); catalogued as COSV67857108; called by muse, mutect2
- SI | c.3937A>G p.R1313G | Missense Mutation (SNP) | VAF 34/637 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs763639584, COSV52288476; called by muse, mutect2
- SLC18B1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV99259331; called by muse, mutect2
- SLC5A2 | c.1178C>G p.S393W | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57894157; called by muse, mutect2, varscan2
- SLC6A12 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs767745827; called by muse, mutect2
- SMYD3 | c.1155G>T p.M385I (on ENST00000490107 / NM_001375962.1; = p.M326I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100830756; called by muse, mutect2, varscan2
- SOX30 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs758664177; called by muse, mutect2
- SYNE1 | c.11800G>T p.V3934F | Missense Mutation (SNP) | VAF 41/621 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV54935744; called by muse, mutect2
- TBC1D12 | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs761177663; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV56695270; called by muse, mutect2, varscan2
- TNNT2 | c.52+6C>T | Splice Region (SNP) | VAF 55/958 reads (6%) | catalogued as rs397516472; ClinVar: uncertain significance; called by muse, mutect2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 76/425 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TRIM64C | c.1287C>G p.I429M | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV73267348; called by muse, mutect2, varscan2
- TRPC7 | c.1386del p.P463Hfs*12 | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | catalogued as COSV61455784; called by mutect2, pindel, varscan2
- USP34 | c.2871C>G p.F957L | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV68402594; called by muse, mutect2, varscan2
- VCAN | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs139358837, COSV54099967; called by mutect2, varscan2
- ZIK1 | c.1165A>G p.S389G | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as rs1166861337, COSV100277452; called by muse, mutect2, varscan2
- ZNF208 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV68105273; called by muse, mutect2
- A1CF | c.1357G>T p.E453* (on ENST00000373993 / NM_138932.2; = p.E445* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- ABCF3 | c.1497C>G p.F499L | Missense Mutation (SNP) | VAF 34/730 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- ABI3BP | c.2359G>T p.G787W | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABL2 | c.179A>C p.E60A (on ENST00000502732 / NM_007314.4; = p.E45A on NM_005158.5) | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ACKR3 | c.1059G>C p.E353D | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADAMTS9 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRD1 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRF3 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGTR1 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AKAP13 | c.4202A>G p.D1401G | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- ALX4 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- APBB1IP | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- AQP9 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGEF25 | c.1130G>C p.R377P | Missense Mutation (SNP) | VAF 38/660 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ASPM | c.3833G>C p.R1278T | Missense Mutation (SNP) | VAF 55/700 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2A3 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2031G>T p.R677S | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP8B3 | c.972C>A p.D324E | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BHLHA15 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); called by mutect2, varscan2
- BICC1 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BIRC6 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); called by muse, mutect2
- BRCA2 | c.8193G>T p.Q2731H | Missense Mutation (SNP) | VAF 51/295 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- BRD4 | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- CARMIL3 | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 42/297 reads (14%) | called by muse, mutect2, varscan2
- CCDC142 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); called by muse, mutect2
- CCDC175 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); called by muse, mutect2
- CDAN1 | c.3451-4G>T | Splice Region (SNP) | VAF 21/384 reads (5%) | called by muse, mutect2
- CDK5RAP2 | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 65/481 reads (14%) | called by muse, mutect2, varscan2
- CELSR3 | c.7747G>T p.G2583W | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CELSR3 | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CELSR3 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP104 | c.566+1G>C p.X189_splice | Splice Site (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- CFAP47 | c.9377A>G p.Y3126C | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHID1 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CHRNB2 | c.783C>A p.D261E | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2
- CIB4 | c.520T>G p.F174V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKAP5 | c.5986G>C p.D1996H (on ENST00000529230 / NM_001008938.4; = p.D1936H on NM_014756.3) | Missense Mutation (SNP) | VAF 75/689 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CKM | c.581T>G p.F194C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- COL16A1 | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COL20A1 | c.2363C>G p.S788C | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); called by muse, mutect2
- CSMD3 | c.4778C>G p.T1593R (on ENST00000297405 / NM_001363185.1; = p.T1489R on NM_052900.3) | Missense Mutation (SNP) | VAF 71/752 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CSTF1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 74/590 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, varscan2
- CTSE | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- DCSTAMP | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 78/765 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- DCSTAMP | c.324G>T p.L108F | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDR2 | c.1003A>T p.T335S | Missense Mutation (SNP) | VAF 65/611 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DDX28 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2
- DENND1B | c.430C>G p.P144A | Missense Mutation (SNP) | VAF 42/433 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- DGCR8 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- DLEC1 | c.1727A>G p.N576S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2
- DLG2 | c.2234T>C p.I745T | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH11 | c.6313A>G p.I2105V | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- DNAJC19 | c.78G>C p.M26I | Missense Mutation (SNP) | VAF 154/2174 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DSTYK | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DTNBP1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DTX3L | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EFEMP2 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ESYT2 | c.1393A>T p.K465* (on ENST00000613624; = p.K389* on NM_020728.3) | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- FAM120A | c.2677G>T p.G893C | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM135A | c.1660A>G p.I554V | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCD2 | c.2588G>C p.R863T | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.302); called by muse, varscan2
- FASLG | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2
- FER1L5 | c.2035C>A p.R679S (on ENST00000623019; = p.R684S on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- FER1L6 | c.4375C>T p.Q1459* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- FLRT3 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GABBR1 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.82); called by muse, mutect2
- GK5 | c.880A>T p.T294S | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- GPR135 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GPR35 | c.483C>G p.F161L | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- GRIA4 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GRIP1 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 128/1046 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HID1 | c.1898C>G p.S633* | Nonsense Mutation (SNP) | VAF 53/226 reads (23%) | called by muse, mutect2, varscan2
- HIVEP2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HMCN1 | c.12510G>T p.R4170S | Missense Mutation (SNP) | VAF 69/388 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HOOK3 | c.1667A>G p.H556R | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HP | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HPS5 | c.349_396del p.V117_D132del (on ENST00000349215 / NM_181507.2; = p.V3_D18del on NM_007216.4) | In Frame Del (DEL) | VAF 16/184 reads (9%) | called by mutect2, pindel
- HRC | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- HSD17B7 | c.609G>C p.L203F | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ILDR2 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.289); called by muse, mutect2
- INO80 | c.3863A>T p.Q1288L | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- ITIH2 | c.1056C>A p.N352K | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.6175G>A p.E2059K | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNA6 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2
- MAD2L1 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAGI2 | c.3985G>C p.E1329Q | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); called by muse, mutect2
- MBTPS1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 70/392 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MECOM | c.2125C>T p.P709S (on ENST00000468789 / NM_001105078.4; = p.P897S on NM_004991.4) | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2
- MKNK1 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MORN3 | c.275C>G p.S92* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MUC16 | c.20619C>A p.D6873E | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by muse, mutect2
- MUC22 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.16); called by muse, mutect2
- NAA16 | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NBEAL1 | c.6388G>T p.A2130S | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); called by muse, mutect2
- NBPF12 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 78/833 reads (9%) | called by muse, mutect2
- NCR1 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NEUROD6 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NFATC2 | c.1811C>A p.T604K | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NIBAN1 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- NPHS1 | c.990C>A p.H330Q | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- NTAN1 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NUF2 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.113); called by muse, mutect2
- ODR4 | c.757G>C p.D253H | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2
- OPA1 | c.166del p.R56Gfs*10 | Frame Shift Del (DEL) | VAF 45/400 reads (11%) | called by mutect2, pindel, varscan2
- OR10C1 | c.655T>G p.Y219D (on ENST00000622521; = p.Y217D on NM_013941.3) | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR12D2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.073); called by muse, mutect2
- OR14C36 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR2T33 | c.796A>T p.T266S | Missense Mutation (SNP) | VAF 52/750 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2
- OR4N2 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXSR1 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- PASD1 | c.818T>G p.L273R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PDE1B | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- PIK3CG | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- PIK3R4 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PINX1 | c.785G>C p.R262T | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1 | c.6750G>C p.L2250F | Missense Mutation (SNP) | VAF 48/671 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.139); called by muse, mutect2
- PLCD3 | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PLD5 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLEKHA2 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 58/664 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2
- PNLIP | c.1-1G>T p.X1_splice | Splice Site (SNP) | VAF 33/242 reads (14%) | called by muse, mutect2, varscan2
- POLR3E | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R3A | c.1117T>A p.S373T | Missense Mutation (SNP) | VAF 19/268 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- PROM1 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PTDSS1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2
- PTK7 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRC | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 160/995 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REPS1 | c.2332G>C p.E778Q (on ENST00000450536 / NM_001286611.2; = p.E777Q on NM_031922.4) | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); called by muse, mutect2
- RNF151 | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RUFY2 | c.1656-3del | Splice Region (DEL) | VAF 18/159 reads (11%) | called by mutect2, pindel
- SERPINA4 | c.1121G>C p.G374A | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SESN3 | c.1469A>G p.H490R | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SETX | c.5104G>T p.V1702F | Missense Mutation (SNP) | VAF 95/755 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SGK3 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 36/378 reads (10%) | called by muse, mutect2
- SH2D3A | c.1435C>A p.R479S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- SH3BP4 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLAMF6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SLC25A40 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SLC5A3 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 21/309 reads (7%) | called by muse, mutect2
- SLC8A1 | c.2096C>A p.A699E | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SOCS5 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2
- SP8 | c.176C>A p.A59D (on ENST00000361443 / NM_198956.4; = p.A77D on NM_182700.6) | Missense Mutation (SNP) | VAF 75/517 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPANXN2 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 124/562 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.426); called by muse, varscan2
- SPEG | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2
- STARD13 | c.1909C>T p.H637Y (on ENST00000336934 / NM_001243476.3; = p.H519Y on NM_052851.3) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- SVIL | c.2062G>T p.E688* (on ENST00000355867 / NM_021738.3; = p.E294* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/285 reads (11%) | called by muse, mutect2, varscan2
- TAS2R31 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- TBX18 | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TFPI | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOP1 | c.1881C>G p.F627L | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIAF1 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- TIMP1 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TM2D2 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 40/882 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TMEM131L | c.4333G>A p.D1445N | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TMEM201 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TRANK1 | c.7168A>G p.M2390V | Missense Mutation (SNP) | VAF 64/559 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRPS1 | c.1993G>C p.E665Q (on ENST00000220888 / NM_001330599.2; = p.E678Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- UBR5 | c.7471G>C p.D2491H | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- UBTF | c.906G>A p.P302= | Splice Region (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- UGT2A3 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTRN | c.10066-2A>T p.X3356_splice | Splice Site (SNP) | VAF 16/156 reads (10%) | called by muse, varscan2
- WDFY4 | c.6808G>T p.E2270* | Nonsense Mutation (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2, varscan2
- WDR92 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.405); called by muse, mutect2
- WNK1 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.36); called by muse, mutect2
- WNK3 | c.4201G>A p.A1401T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- WRN | c.3004A>T p.S1002C | Missense Mutation (SNP) | VAF 61/486 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZBTB49 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZDHHC21 | c.169T>G p.S57A | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZFHX4 | c.8818C>G p.Q2940E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZFX | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF23 | c.509G>C p.C170S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2
- ZNF519 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ZNF565 | c.594G>C p.Q198H (on ENST00000355114; = p.Q158H on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ZNF678 | c.439C>G p.H147D (on ENST00000343776 / NM_001367910.1; = p.H202D on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCB1 | c.1812A>T p.G604= | Silent (SNP) | VAF 33/414 reads (8%) | catalogued as COSV55956364; called by muse, mutect2
- ACP3 | c.252T>C p.Y84= | Silent (SNP) | VAF 54/328 reads (16%) | catalogued as rs762344566; called by muse, mutect2, varscan2
- ACSBG2 | c.1620C>A p.I540= | Silent (SNP) | VAF 27/247 reads (11%) | called by muse, mutect2, varscan2
- ADARB1 | c.375C>T p.P125= | Silent (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- ADCY8 | c.1062G>T p.R354= | Silent (SNP) | VAF 50/337 reads (15%) | called by muse, varscan2
- ADD2 | c.456G>C p.L152= | Silent (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1704A>T p.I568= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- ADGRG4 | c.181C>T p.L61= | Silent (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- ANK1 | c.2706C>T p.I902= | Silent (SNP) | VAF 32/470 reads (7%) | catalogued as rs1394526092, COSV55895582; called by muse, mutect2
- ARHGAP5 | c.3504T>C p.Y1168= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs1566662697, COSV61537330; called by muse, mutect2
- C19orf25 | c.90G>T p.A30= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1182345481; called by muse, mutect2, varscan2
- C19orf84 | c.517C>T p.L173= | Silent (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- CACNG8 | c.1254C>G p.L418= | Silent (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- CBLB | c.2385C>A p.L795= | Silent (SNP) | VAF 49/552 reads (9%) | called by muse, mutect2
- CTNND2 | c.2061T>A p.I687= | Silent (SNP) | VAF 24/222 reads (11%) | called by muse, mutect2, varscan2
- CYTH1 | c.399G>C p.L133= | Silent (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- DCTD | c.210A>G p.T70= | Silent (SNP) | VAF 49/336 reads (15%) | called by muse, mutect2, varscan2
- ERCC3 | c.1404G>T p.A468= | Silent (SNP) | VAF 41/309 reads (13%) | catalogued as rs1220554914, COSV53426348; called by muse, mutect2, varscan2
- FAT3 | c.8754T>C p.N2918= | Silent (SNP) | VAF 29/293 reads (10%) | called by muse, mutect2
- FOXG1 | c.1032G>C p.V344= | Silent (SNP) | VAF 94/765 reads (12%) | catalogued as rs765799544; called by muse, mutect2, varscan2
- FZD5 | c.375C>T p.F125= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1407775567, COSV54944839; called by muse, mutect2, varscan2
- GFRAL | c.204G>C p.L68= | Silent (SNP) | VAF 25/156 reads (16%) | called by muse, mutect2, varscan2
- GHSR | c.186G>C p.L62= | Silent (SNP) | VAF 66/325 reads (20%) | called by muse, mutect2, varscan2
- GNAS | c.2037C>T p.G679= | Silent (SNP) | VAF 34/618 reads (6%) | called by muse, mutect2
- HERC5 | c.2289G>A p.E763= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs910874848; called by muse, varscan2
- HTRA4 | c.213C>G p.V71= | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- IGHV2-5 | c.15C>T p.C5= | Silent (SNP) | VAF 52/294 reads (18%) | catalogued as rs1555425693; called by muse, mutect2, varscan2
- INSR | c.1251A>G p.G417= | Silent (SNP) | VAF 86/760 reads (11%) | catalogued as rs767530831; called by muse, mutect2, varscan2
- ITPRID1 | c.90G>T p.A30= | Silent (SNP) | VAF 26/275 reads (9%) | catalogued as rs771087429; called by muse, mutect2
- KIAA1210 | c.921A>T p.P307= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, varscan2
- LAMA2 | c.7728A>G p.R2576= | Silent (SNP) | VAF 40/662 reads (6%) | called by muse, mutect2
- MTMR2 | c.861C>T p.P287= | Silent (SNP) | VAF 65/381 reads (17%) | called by muse, mutect2, varscan2
- MYH15 | c.744C>G p.T248= | Silent (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- NAF1 | c.726G>A p.E242= | Silent (SNP) | VAF 26/291 reads (9%) | called by muse, mutect2
- NECTIN4 | c.546C>A p.T182= | Silent (SNP) | VAF 99/372 reads (27%) | called by muse, mutect2, varscan2
- NPAP1 | c.3174C>A p.A1058= | Silent (SNP) | VAF 39/361 reads (11%) | called by muse, mutect2, varscan2
- OR2T10 | c.720C>T p.T240= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs140690496; called by muse, mutect2, varscan2
- OR2T3 | c.870G>T p.L290= | Silent (SNP) | VAF 74/699 reads (11%) | catalogued as COSV62081992; called by mutect2, varscan2
- OR2T33 | c.156G>C p.R52= | Silent (SNP) | VAF 36/417 reads (9%) | called by muse, mutect2
- OR4S2 | c.558C>A p.A186= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs781138224; called by muse, mutect2, varscan2
- OTUD7B | c.1452G>A p.R484= | Silent (SNP) | VAF 96/467 reads (21%) | called by muse, mutect2, varscan2
- PAQR9 | c.117G>T p.A39= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- PAX7 | c.1116C>T p.S372= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as COSV64749407; called by muse, varscan2
- PDILT | c.699C>A p.R233= | Silent (SNP) | VAF 34/266 reads (13%) | called by muse, mutect2, varscan2
- PFKM | c.189A>T p.I63= | Silent (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- PIK3C2B | c.2223C>T p.F741= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, varscan2
- PLOD3 | c.474C>A p.G158= | Silent (SNP) | VAF 33/350 reads (9%) | called by muse, mutect2
- POLG | c.3693G>A p.L1231= | Silent (SNP) | VAF 74/634 reads (12%) | called by muse, mutect2, varscan2
- POP4 | c.33G>A p.Q11= | Silent (SNP) | VAF 14/316 reads (4%) | catalogued as rs1270317129; called by muse, mutect2
- PRKAR1A | c.1050G>T p.L350= | Silent (SNP) | VAF 158/670 reads (24%) | catalogued as COSV56836963; called by muse, mutect2, varscan2
- PRPF6 | c.537G>A p.L179= | Silent (SNP) | VAF 76/450 reads (17%) | called by muse, mutect2, varscan2
- QPCTL | c.141G>T p.A47= | Silent (SNP) | VAF 30/204 reads (15%) | called by muse, mutect2, varscan2
- RCBTB1 | c.1116G>T p.L372= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as COSV99319602; called by muse, mutect2, varscan2
- RELB | c.1257T>A p.L419= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- RING1 | c.48G>C p.L16= | Silent (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- RPIA | c.135G>A p.G45= | Silent (SNP) | VAF 27/207 reads (13%) | called by muse, mutect2, varscan2
- RUBCNL | c.846C>T p.V282= | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as rs1430094059; called by muse, mutect2
- SEL1L2 | c.1926C>A p.L642= | Silent (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- SIRPB1 | c.42C>T p.F14= | Silent (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- SLC12A7 | c.1176G>A p.K392= | Silent (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- SLC29A4 | c.897G>A p.P299= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs560946430; called by muse, mutect2, varscan2
- SLC2A13 | c.651A>G p.T217= | Silent (SNP) | VAF 51/380 reads (13%) | catalogued as COSV55120404; called by muse, mutect2, varscan2
- SPANXN1 | c.42G>A p.K14= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as COSV100979306, COSV65122783; called by muse, mutect2, varscan2
- SVOPL | c.180T>G p.V60= | Silent (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.12312G>T p.V4104= (on ENST00000367255 / NM_182961.4; = p.V4033= on NM_033071.3) | Silent (SNP) | VAF 42/725 reads (6%) | called by muse, mutect2
- TBXT | c.762G>T p.L254= | Silent (SNP) | VAF 21/205 reads (10%) | catalogued as COSV51619408, COSV99752156; called by muse, mutect2
- TMEM200B | c.168G>A p.A56= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs756589878; called by muse, mutect2, varscan2
- TRAM2 | c.930C>T p.F310= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as rs764609476, COSV51731430; called by muse, mutect2, varscan2
- TRIM67 | c.1389G>C p.L463= | Silent (SNP) | VAF 33/230 reads (14%) | catalogued as COSV100792168; called by muse, mutect2, varscan2
- TTN | c.38124C>A p.G12708= (on ENST00000591111; = p.G5284= on NM_003319.4) | Silent (SNP) | VAF 16/282 reads (6%) | catalogued as COSV60358784; called by muse, mutect2
- TYW1 | c.126C>T p.I42= | Silent (SNP) | VAF 28/276 reads (10%) | catalogued as COSV55887052; called by muse, mutect2
- UMODL1 | c.393C>A p.S131= | Silent (SNP) | VAF 22/266 reads (8%) | catalogued as rs374646869; called by muse, mutect2
- URB1 | c.4941C>T p.F1647= | Silent (SNP) | VAF 24/541 reads (4%) | catalogued as COSV66961612; called by muse, mutect2
- USH2A | c.7086A>G p.S2362= | Silent (SNP) | VAF 42/512 reads (8%) | called by muse, mutect2
- VPS13D | c.10899A>G p.R3633= | Silent (SNP) | VAF 30/225 reads (13%) | catalogued as rs756090819; called by muse, mutect2, varscan2
- VSNL1 | c.81C>G p.L27= | Silent (SNP) | VAF 36/498 reads (7%) | called by muse, mutect2
- WFDC8 | c.468C>G p.L156= | Silent (SNP) | VAF 28/209 reads (13%) | called by muse, mutect2, varscan2
- ZNF208 | c.768C>A p.S256= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- ZNF607 | c.792C>G p.L264= | Silent (SNP) | VAF 38/363 reads (10%) | catalogued as COSV67697206; called by muse, mutect2, varscan2
- ZNF90 | c.984T>C p.L328= | Silent (SNP) | VAF 25/388 reads (6%) | called by muse, mutect2
- ZP3 | c.189G>A p.G63= (on ENST00000394857 / NM_001110354.2; = p.G12= on NM_007155.6) | Silent (SNP) | VAF 31/311 reads (10%) | catalogued as rs552823307, COSV60632015; called by muse, mutect2, varscan2
- ZSCAN1 | c.984C>A p.V328= | Silent (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- ABAT | c.-41-21829G>T | Intron (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- ABCG5 | c.143+48C>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs757833053; called by muse, varscan2
- AGMO | c.1263+7100T>A | Intron (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- ANKRD20A8P | n.1272C>G | RNA (SNP) | VAF 54/538 reads (10%) | catalogued as rs368471245, COSV71422560; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1512C>A | RNA (SNP) | VAF 21/448 reads (5%) | called by muse, mutect2
- ARHGAP9 | c.-203-11C>G | Intron (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- BTN2A3P | n.1448-23C>G | Intron (SNP) | VAF 35/593 reads (6%) | called by muse, mutect2
- C2CD6 | c.1582-3698C>G | Intron (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2
- C7orf25 | c.-160C>G | 5'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs367610420; called by mutect2, varscan2
- CD55 | c.1081+8100C>T | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CELF4 | c.1165+32C>G | Intron (SNP) | VAF 19/179 reads (11%) | called by muse, mutect2, varscan2
- CHN1 | c.*290A>T | 3'UTR (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- COMMD4P1 | n.201-261C>T | Intron (SNP) | VAF 25/229 reads (11%) | catalogued as rs764306018; called by muse, mutect2, varscan2
- COPS7A | c.163-224G>A | Intron (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- DRD2 | c.810+71G>C | Intron (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- EMSY | c.3774+770G>A | Intron (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- EVA1B | chr1:36328024 C>T | 5'Flank (SNP) | VAF 66/600 reads (11%) | catalogued as rs771663403; called by muse, mutect2, varscan2
- FHL1 | c.*416C>T | 3'UTR (SNP) | VAF 34/147 reads (23%) | catalogued as rs777576309; called by muse, mutect2, varscan2
- GPATCH4 | chr1:156595191 C>G | 3'Flank (SNP) | VAF 55/292 reads (19%) | called by muse, mutect2, varscan2
- GRIK1 | c.1794-793G>A | Intron (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- HDGFL3 | c.607-5270G>A | Intron (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2
- IL10RA | c.-17G>C | 5'UTR (SNP) | VAF 22/149 reads (15%) | catalogued as rs368849726; called by muse, mutect2, varscan2
- JAKMIP2 | c.2413-2677G>C | Intron (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- KLHL14 | c.-43-357C>T | Intron (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- KMT5C | c.570+886G>C | Intron (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- KRT18P23 | chr22:44569403 G>T | 3'Flank (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- LBX1 | chr10:101232384 C>G | 5'Flank (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- LPIN1 | c.1250+52C>G | Intron (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- LRATD1 | n.584A>G | RNA (SNP) | VAF 23/248 reads (9%) | called by muse, mutect2
- MASP1 | c.1303+5496A>T | Intron (SNP) | VAF 76/666 reads (11%) | called by muse, mutect2, varscan2
- MEFV | c.1610+25C>A | Intron (SNP) | VAF 49/361 reads (14%) | called by muse, mutect2, varscan2
- MIR34AHG | n.1868C>G | RNA (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- MIR4771-1 | chr2:87193475 A>G | 5'Flank (SNP) | VAF 13/160 reads (8%) | called by muse, mutect2, varscan2
- MIR6511A3 | chr16:16372491 C>T | 3'Flank (SNP) | VAF 11/104 reads (11%) | catalogued as rs1176216275; called by mutect2, varscan2
- MPRIP | c.2164-2880G>T | Intron (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- MRPL49 | c.354+41C>G | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs375509318; called by muse, mutect2, varscan2
- MSC-AS1 | n.332A>G | RNA (SNP) | VAF 58/601 reads (10%) | called by muse, mutect2
- MSL3P1 | n.923A>T | RNA (SNP) | VAF 30/195 reads (15%) | called by muse, mutect2, varscan2
- NEK2 | chr1:211658674 C>G | 3'Flank (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NPHP4 | c.3644+27G>C | Intron (SNP) | VAF 41/355 reads (12%) | called by muse, mutect2, varscan2
- PCNX3 | c.3379+135C>T | Intron (SNP) | VAF 39/314 reads (12%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1845+4121A>C | Intron (SNP) | VAF 29/247 reads (12%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128799 C>G | 5'Flank (SNP) | VAF 40/299 reads (13%) | called by muse, mutect2, varscan2
- PYGM | c.*71G>C | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- RABEP2 | c.275-1229A>G | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- SLC25A4 | c.-18G>C | 5'UTR (SNP) | VAF 25/215 reads (12%) | catalogued as rs961652360; called by muse, mutect2, varscan2
- SLC26A4 | c.-3-23C>G | Intron (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- SLC29A3 | c.-48G>T | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- SMPD4BP | n.2455C>T | RNA (SNP) | VAF 9/151 reads (6%) | catalogued as rs1454570251; called by muse, mutect2
- TMEM184A | c.1-26G>T | Intron (SNP) | VAF 33/266 reads (12%) | catalogued as COSV52473607; called by muse, mutect2, varscan2
- TPPP2 | chr14:21035815 G>A | 3'Flank (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- TTN | c.10360+3218C>G | Intron (SNP) | VAF 56/557 reads (10%) | called by muse, mutect2, varscan2
- UBTFL2 | n.687G>T | RNA (SNP) | VAF 36/586 reads (6%) | called by muse, mutect2
- UMOD | c.89-633G>T | Intron (SNP) | VAF 23/212 reads (11%) | catalogued as COSV56779076; called by muse, varscan2
- XIAP | c.*6637G>C | 3'UTR (SNP) | VAF 16/111 reads (14%) | catalogued as rs114568994, COSV63022620; called by muse, mutect2
- ZNF252P | n.1853G>T | RNA (SNP) | VAF 41/306 reads (13%) | called by muse, mutect2, varscan2
- ZNF729 | c.-54G>T | 5'UTR (SNP) | VAF 20/223 reads (9%) | called by muse, mutect2
